Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QN, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QN-01A (Primary Tumor).

[page 1 of 3]
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

ICA-0-3 Carcinoma, Papillary, Thyroid 8260/3
Site: thyroid, NOS C73.9 hr 3/16/11

Clinical Diagnosis & History:

Papillary carcinoma in a multinodular goiter.

Specimens Submitted:

- 1: SP: Thyroid, right thyroid lobe and isthmus, lobectomy
- 2: SP: Thyroid, left thyroid lobe, lobectomy

DIAGNOSIS:

1. SP: Thyroid, right thyroid lobe and isthmus, lobectomy:

Tumor Type:

Papillary microcarcinoma

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 0.1 cm.

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

[page 2 of 3]
2. **SP: Thyroid, left thyroid lobe, lobectomy:**

Tumor Type:

Three foci of papillary carcinoma; One classical type, one follicular variant, and one microcarcinoma

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

The classical type measures 1.5 cm, the follicular variant measures 1.2 cm and the microcarcinoma measures < 0.1 cm

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Focal invasion
for the classical type

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Gross and microscopic foci

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Parathyroid Glands:

Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 3 of 3]
1.) The specimen is received fresh and is labeled "Right thyroid lobe and isthmus, long stitch -- superior, short stitch pyramidal lobe". It consists of an oriented, 7.0 g, 3.8 x 2.3 x 1.6 cm right thyroid lobe, with attached 1.9 x 1.1 x 0.8 cm isthmus and 1.5 x 1.1 x 0.4 cm pyramidal lobe. A long stitch designates the superior aspect of the right thyroid lobe and a short stitch designates the pyramidal lobe. The surface is shaggy and pink-purple. The lobe is inked black posterior and blue anterior. Serial sectioning reveals two abutting, poorly defined, soft, tan-white to tan-yellow circumscribed nodules, ranging from 0.2 to 0.7 cm in greatest dimension. Both nodules are located within the mid to lower right lobe and are located 0.1 cm from both the anterior and posterior intact thyroid capsule. A capsule is not identified grossly surrounding either nodule. The remaining thyroid parenchyma is meaty and tan-red. Entirely submitted.

Summary of sections:

NS - abutting nodules

RRL -- remaining right lobe, superior to inferior

PI -- pyramidal with attached isthmus, superior to inferior

2. The specimen is received fresh and is labeled "left thyroid lobe, stitch left superior pole". It consists of a thyroid lobe measuring 4 x 3.5 x 1.0 cm and weighing 8 g with a suture marking the superior pole. The surface shows few nodules one closer to superior pole measures 1.5 x 1.2 x 1.0 cm with slightly granular cut surface and the second one closer to inferior end measures 1.2 x 1.0 x 1.0 cm. The lobe is inked black posterior and blue anterior. TPS submitted from both nodules. Entirely submitted.

Summary of sections:

N1 - nodule 1 near superior pole

N2- nodule2 near the lower end

RS - remaining sections

Summary of Sections:

Part 1: SP: Thyroid, right thyroid lobe and isthmus, lobectomy

Block	Sect. Site	PCs
3	NS	3
3	PI	8
6	RRL	12

Part 2: SP: Thyroid, left thyroid lobe, lobectomy

Block	Sect. Site	PCs
2	n1	2
2	n2	2
3	rs	3

Source: NCI Genomic Data Commons file d2583a1e-c7a6-4349-af20-e247bb092c9b (TCGA-DJ-A1QN.99CA27B4-D3B7-4D4A-80D4-AADF587EA52D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).